Somatic mutation profile of tumor specimen 0DTB92 from CCDI case PBCJJX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 22.3 years (8,138 days).
Specimen 0DTB92: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7efd4219-23e3-4f21-b1b3-9ffd84fb5613.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTB8M (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d881f59-85a2-43a6-af73-f3a08365a362

The open-access MAF lists 48 somatic variants for this specimen: 28 protein-altering or splice-affecting, 14 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 14, Intron 3, Nonsense Mutation 3, 5'UTR 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 158/589 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 491/660 reads (74%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HSPA12A | c.1154C>T p.A385V | Missense Mutation (SNP) | VAF 189/684 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1554878294, COSV65022160, COSV65022885; called by muse, mutect2, varscan2
- JCAD | c.3284C>T p.A1095V | Missense Mutation (SNP) | VAF 97/254 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs12240677, COSV64759559; called by muse, mutect2, varscan2
- KIF27 | c.2815C>T p.R939C | Missense Mutation (SNP) | VAF 147/908 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs3199677; called by muse, mutect2, varscan2
- LRRIQ1 | c.2971C>A p.P991T | Missense Mutation (SNP) | VAF 152/1089 reads (14%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.982); catalogued as rs200596040; called by muse, varscan2
- LRRIQ1 | c.2972C>A p.P991H | Missense Mutation (SNP) | VAF 152/1100 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV67827478; called by muse, varscan2
- NYAP2 | c.1385C>T p.S462L | Missense Mutation (SNP) | VAF 265/913 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs865814391, COSV56000740; called by muse, mutect2, varscan2
- PPARA | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 222/937 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs1389815337, COSV53079487; called by muse, mutect2, varscan2
- PTPRA | c.301A>G p.I101V | Missense Mutation (SNP) | VAF 93/1068 reads (9%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV53785128; called by muse, mutect2
- RPP40 | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 33/620 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.348); catalogued as rs765981570; called by muse, mutect2
- SDR9C7 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 112/873 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.378); catalogued as rs150520393, COSV53290314; called by muse, mutect2, varscan2
- SIX5 | c.382C>A p.R128S | Missense Mutation (SNP) | VAF 22/218 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as rs1350446479; called by muse, mutect2, varscan2
- SPDYE16 | c.817C>T p.R273W | Missense Mutation (SNP) | VAF 164/341 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as rs1306548744; called by muse, mutect2, varscan2
- STK10 | c.1094C>T p.P365L | Missense Mutation (SNP) | VAF 107/738 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs779604842, COSV51570465; called by muse, varscan2
- VTN | c.1171C>T p.Q391* | Nonsense Mutation (SNP) | VAF 70/230 reads (30%) | catalogued as COSV52648021; called by muse, mutect2, varscan2
- CCR1 | c.179T>C p.V60A | Missense Mutation (SNP) | VAF 29/469 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2
- FEM1B | c.808A>G p.I270V | Missense Mutation (SNP) | VAF 499/1211 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITPR3 | c.2482A>T p.N828Y | Missense Mutation (SNP) | VAF 143/1255 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.73); called by muse, mutect2, varscan2
- MDN1 | c.8966G>C p.R2989P | Missense Mutation (SNP) | VAF 202/1630 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- MORN1 | c.548A>G p.H183R | Missense Mutation (SNP) | VAF 135/414 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NIPBL | c.2934G>A p.M978I | Missense Mutation (SNP) | VAF 56/2130 reads (3%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); called by muse, mutect2
- NRG1 | c.680T>C p.M227T | Missense Mutation (SNP) | VAF 173/1390 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PNPLA1 | c.882A>T p.Q294H (on ENST00000394571 / NM_001374623.1; = p.Q199H on NM_173676.2) | Missense Mutation (SNP) | VAF 77/754 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- PRSS1 | c.599C>A p.S200Y | Missense Mutation (SNP) | VAF 105/1081 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SNX5 | c.538A>T p.K180* | Nonsense Mutation (SNP) | VAF 209/1527 reads (14%) | called by muse, mutect2, varscan2
- SOX8 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 23/621 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ZNF611 | c.257A>G p.H86R | Missense Mutation (SNP) | VAF 329/1276 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- ADAM8 | c.30C>T p.G10= | Silent (SNP) | VAF 53/542 reads (10%) | called by muse, mutect2
- AHNAK2 | c.3663G>A p.E1221= | Silent (SNP) | VAF 48/195 reads (25%) | called by muse, varscan2
- ANKRD34C | c.249G>A p.K83= | Silent (SNP) | VAF 85/681 reads (12%) | catalogued as rs1350466273, COSV69854375; called by muse, mutect2, varscan2
- CKB | c.714C>T p.I238= | Silent (SNP) | VAF 104/1136 reads (9%) | catalogued as COSV62379601; called by muse, mutect2
- CSF2RA | c.741G>A p.S247= | Silent (SNP) | VAF 130/603 reads (22%) | catalogued as rs761160075, COSV100817685, COSV62627212; called by muse, mutect2, varscan2
- GRIN3B | c.1173C>T p.D391= | Silent (SNP) | VAF 25/256 reads (10%) | catalogued as rs753538459, COSV52259706; called by muse, mutect2, varscan2
- IQCD | c.978G>C p.V326= | Silent (SNP) | VAF 42/1028 reads (4%) | called by muse, mutect2
- KPTN | c.1167C>T p.G389= | Silent (SNP) | VAF 44/554 reads (8%) | catalogued as rs562237338, COSV52637719; ClinVar: uncertain significance; called by muse, mutect2
- LRRIQ1 | c.2973T>A p.P991= | Silent (SNP) | VAF 152/1104 reads (14%) | called by muse, varscan2
- PLCB3 | c.3696G>A p.T1232= | Silent (SNP) | VAF 105/471 reads (22%) | catalogued as rs774371078; called by muse, mutect2, varscan2
- SERPINA5 | c.651C>T p.G217= | Silent (SNP) | VAF 42/658 reads (6%) | called by muse, mutect2
- TGM1 | c.333A>G p.V111= | Silent (SNP) | VAF 26/961 reads (3%) | called by muse, mutect2
- TUBGCP2 | c.1854C>T p.F618= | Silent (SNP) | VAF 97/721 reads (13%) | catalogued as rs543843952, COSV53306981; called by muse, mutect2, varscan2
- VWA1 | c.486C>T p.G162= | Silent (SNP) | VAF 67/248 reads (27%) | catalogued as rs150311038; called by muse, mutect2, varscan2
- ABHD15 | c.-71G>C | 5'UTR (SNP) | VAF 4/21 reads (19%) | called by muse, mutect2, varscan2
- BIRC6 | c.13144+8167A>G | Intron (SNP) | VAF 73/653 reads (11%) | catalogued as COSV70203370; called by muse, mutect2, varscan2
- HMGN1 | c.16-9T>G | Intron (SNP) | VAF 214/608 reads (35%) | called by mutect2, varscan2
- HNF4A | c.115+1084T>A | Intron (SNP) | VAF 158/492 reads (32%) | called by muse, mutect2, varscan2
- HSFX4 | c.*91del | 3'UTR (DEL) | VAF 19/94 reads (20%) | called by mutect2, varscan2
- TEX50 | c.-37A>T | 5'UTR (SNP) | VAF 47/459 reads (10%) | called by muse, mutect2, varscan2
